Somatic mutation profile of tumor specimen 0E03VB from CCDI case PBCUUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E03VB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e57d2038-5b08-4baa-8c2f-5c3ca1429768.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E03W9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bfc72d6-33e7-403e-985f-c9ff5f111973

The open-access MAF lists 92 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, 3'UTR 6, Nonsense Mutation 4, Intron 3, Frame Shift Ins 2, Splice Region 1, In Frame Ins 1, 5'UTR 1, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF1 | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 61/491 reads (12%) | catalogued as COSV51604329; called by muse, mutect2, varscan2
- CASR | c.2848G>A p.V950I (on ENST00000490131; = p.V1027I on NM_000388.4) | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs776184769, COSV56135332; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL23A1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs373742794; called by muse, mutect2, varscan2
- COL4A6 | c.2518+2T>C p.X840_splice | Splice Site (SNP) | VAF 59/126 reads (47%) | catalogued as COSV57866332; called by muse, mutect2, varscan2
- CSH2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs377538456; called by muse, mutect2, varscan2
- CYP4X1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs371700658; called by muse, mutect2, varscan2
- DCBLD1 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 71/401 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774801446; called by muse, mutect2, varscan2
- DZIP1 | c.1843G>A p.D615N (on ENST00000347108; = p.D596N on NM_014934.5) | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV61269523; called by muse, mutect2, varscan2
- GCG | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 105/681 reads (15%) | catalogued as COSV64961276; called by muse, mutect2, varscan2
- GLI3 | c.2411T>C p.V804A | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV101229947; called by muse, mutect2, varscan2
- HS6ST3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 72/605 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs746839989, COSV65009473; called by muse, mutect2, varscan2
- HTR1E | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV59506529, COSV59509264; called by muse, mutect2, varscan2
- LDLRAD3 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 53/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59679649; called by muse, mutect2, varscan2
- LRFN3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as rs368411312; called by muse, mutect2
- MCIDAS | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 69/383 reads (18%) | catalogued as COSV72813283; called by muse, mutect2, varscan2
- MEPCE | c.508C>A p.R170S | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52769425; called by muse, mutect2, varscan2
- MMP28 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs532783200; called by muse, mutect2, varscan2
- NALCN | c.1823T>A p.L608Q | Missense Mutation (SNP) | VAF 63/615 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51916313; called by muse, mutect2, varscan2
- NR4A2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59895074; called by muse, mutect2, varscan2
- OR10J5 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV58387494; called by muse, mutect2, varscan2
- OR52I2 | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100442887; called by muse, mutect2, varscan2
- PAPLN | c.2611del p.H871Tfs*93 (on ENST00000554301; = p.H844Tfs*93 on NM_173462.4) | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs1291107616; called by mutect2, pindel, varscan2
- RPS6KB2 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57053249; called by muse, mutect2, varscan2
- RTL9 | c.741G>C p.M247I | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV104438323; called by muse, mutect2, varscan2
- SMTN | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as rs375442203; called by muse, mutect2
- SPATA31D1 | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.754); catalogued as COSV61199238; called by muse, mutect2, varscan2
- VWC2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61483836, COSV61485442; called by muse, mutect2, varscan2
- ZSCAN1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs145743431, COSV56603241; called by muse, mutect2
- AMT | c.551-8G>A | Splice Region (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- APPL1 | c.243_245dup p.V81_M82insI | In Frame Ins (INS) | VAF 77/452 reads (17%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.2681C>A p.T894K | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.011); called by mutect2, varscan2
- C19orf18 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 50/564 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- C1orf226 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CC2D2A | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHADL | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COL10A1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNHD1 | c.5497C>G p.R1833G | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DSG2 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENKUR | c.89T>G p.I30S | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ERG | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FOXD4L1 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GBP1 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GGCT | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 49/793 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA6L2 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated, low confidence (0.13); called by muse, varscan2
- GTF2E2 | c.822C>G p.N274K | Missense Mutation (SNP) | VAF 68/582 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGXB4 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- INTS12 | c.1130T>G p.V377G | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPRE3 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 53/279 reads (19%) | called by muse, mutect2, varscan2
- MGAM2 | c.3051G>T p.R1017S | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1L | c.3336C>G p.N1112K | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NCOA2 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 75/659 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- NETO2 | c.1491_1494dup p.V500Pfs*9 | Frame Shift Ins (INS) | VAF 48/279 reads (17%) | called by mutect2, pindel, varscan2
- OR8H1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PCDH9 | c.3649G>T p.A1217S (on ENST00000377865 / NM_203487.3; = p.A1183S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/1022 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.124); called by muse, mutect2
- PKD2L1 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM9 | c.1287T>A p.N429K | Missense Mutation (SNP) | VAF 80/472 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRR18 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SAMD14 | c.1207_1211dup p.E405Sfs*112 (on ENST00000330175 / NM_001257359.2; = p.E433Sfs*? on NM_174920.4) | Frame Shift Ins (INS) | VAF 31/178 reads (17%) | called by mutect2, pindel, varscan2
- SEMA3A | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 96/849 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SLC15A2 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLITRK3 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- TESC | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2
- AHCYL2 | c.1029G>T p.L343= | Silent (SNP) | VAF 73/701 reads (10%) | called by muse, mutect2, varscan2
- ARFGAP3 | c.756G>A p.A252= | Silent (SNP) | VAF 93/545 reads (17%) | catalogued as rs145699759; called by muse, mutect2, varscan2
- BRINP1 | c.2049C>A p.G683= | Silent (SNP) | VAF 45/170 reads (26%) | called by muse, mutect2, varscan2
- DARS2 | c.258C>T p.F86= | Silent (SNP) | VAF 81/401 reads (20%) | catalogued as rs1043805425, COSV53407455; called by muse, mutect2, varscan2
- ESX1 | c.780T>C p.P260= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- MAK16 | c.663C>G p.V221= | Silent (SNP) | VAF 94/456 reads (21%) | catalogued as COSV62452321; called by muse, mutect2, varscan2
- MUC17 | c.51G>T p.S17= | Silent (SNP) | VAF 33/297 reads (11%) | catalogued as COSV59332162; called by muse, mutect2, varscan2
- MUC5AC | c.10392C>A p.S3464= | Silent (SNP) | VAF 46/220 reads (21%) | called by muse, mutect2, varscan2
- MYO15A | c.4239C>T p.Y1413= | Silent (SNP) | VAF 50/243 reads (21%) | called by muse, mutect2, varscan2
- MYO18B | c.2934G>T p.L978= | Silent (SNP) | VAF 54/430 reads (13%) | called by muse, mutect2, varscan2
- OR5F1 | c.342C>A p.L114= | Silent (SNP) | VAF 38/285 reads (13%) | called by muse, mutect2, varscan2
- PCDHA8 | c.2046G>A p.Q682= | Silent (SNP) | VAF 65/193 reads (34%) | catalogued as rs533829859; called by muse, mutect2, varscan2
- PDE10A | c.1245C>T p.A415= | Silent (SNP) | VAF 76/411 reads (18%) | catalogued as rs781419069, COSV63050104; called by muse, mutect2, varscan2
- PXDNL | c.1329C>T p.D443= | Silent (SNP) | VAF 73/518 reads (14%) | catalogued as rs377262954; called by muse, mutect2, varscan2
- SEMA3A | c.1704A>T p.S568= | Silent (SNP) | VAF 92/854 reads (11%) | called by muse, mutect2, varscan2
- SH3RF2 | c.1077C>T p.P359= | Silent (SNP) | VAF 76/241 reads (32%) | catalogued as rs781055446; called by muse, mutect2, varscan2
- SPANXN3 | c.258C>T p.D86= | Silent (SNP) | VAF 71/171 reads (42%) | catalogued as rs369110331, COSV65140047; called by muse, varscan2
- SUGP1 | c.1863G>A p.A621= | Silent (SNP) | VAF 47/279 reads (17%) | catalogued as rs200033194, COSV55921232; called by muse, mutect2, varscan2
- XPO4 | c.1710T>C p.I570= | Silent (SNP) | VAF 74/821 reads (9%) | called by muse, mutect2
- CNPY3 | c.*87C>T | 3'UTR (SNP) | VAF 12/51 reads (24%) | catalogued as rs1319940831; called by muse, mutect2, varscan2
- CREB1 | c.*4G>T | 3'UTR (SNP) | VAF 96/343 reads (28%) | called by muse, mutect2, varscan2
- HGSNAT | c.-26C>G | 5'UTR (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- ICA1L | c.*100G>A | 3'UTR (SNP) | VAF 12/75 reads (16%) | catalogued as rs1028962657; called by muse, mutect2, varscan2
- LCK | c.*52G>T | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- LILRB2 | c.*13G>A | 3'UTR (SNP) | VAF 42/329 reads (13%) | catalogued as rs1274217244; called by muse, mutect2, varscan2
- MUC19 | n.13260C>A | RNA (SNP) | VAF 44/244 reads (18%) | called by muse, mutect2, varscan2
- POP5 | c.314-19A>T | Intron (SNP) | VAF 69/339 reads (20%) | called by muse, mutect2, varscan2
- SFSWAP | c.2409-1185G>T | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as rs1467469293; called by muse, mutect2, varscan2
- TNFAIP1 | c.*57G>A | 3'UTR (SNP) | VAF 21/93 reads (23%) | catalogued as rs1349079468, COSV99134844; called by muse, mutect2, varscan2
- XAB2 | c.201-30G>T | Intron (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
